Somatic mutation profile of tumor specimen TCGA-41-3915-01A (aliquot TCGA-41-3915-01A-01D-1353-08) from TCGA case TCGA-41-3915, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.0 years (17,880 days).
Specimen TCGA-41-3915-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8e9bffb-5d56-4056-a06a-37267226a621.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-41-3915-10A (Blood Derived Normal), aliquot TCGA-41-3915-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b918ab6e-cfec-40e8-af6e-fdaabfe04148

The open-access MAF lists 38 somatic variants for this specimen: 25 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 20, Silent 13, Frame Shift Ins 2, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 135/192 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTSL1 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759980544, COSV52813321; called by muse, mutect2
- ADCY2 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs754041062, COSV57866829; called by muse, mutect2, varscan2
- AHNAK2 | c.8158C>A p.H2720N | Missense Mutation (SNP) | VAF 83/340 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.227); catalogued as COSV60911976, COSV60912229; called by muse, mutect2, varscan2
- BCAM | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 98/302 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV54301554; called by muse, varscan2
- CEP170 | c.3469C>T p.R1157* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100316435; called by mutect2, varscan2
- CPNE8 | c.112A>T p.R38* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV58840097, COSV58841172; called by muse, mutect2, varscan2
- DENND5A | c.2689C>T p.L897F | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60232808; called by muse, mutect2, varscan2
- DNAI3 | c.977A>T p.Q326L | Missense Mutation (SNP) | VAF 69/289 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV54001700; called by muse, mutect2, varscan2
- FOXI1 | c.397G>C p.A133P | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60387927, COSV60388411; called by muse, varscan2
- GC | c.1105C>G p.L369V | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs752958552, COSV56736653; called by muse, mutect2, varscan2
- HP1BP3 | c.13dup p.T5Nfs*5 | Frame Shift Ins (INS) | VAF 49/133 reads (37%) | catalogued as rs1557675666; called by mutect2, pindel, varscan2
- KRT37 | c.1253A>G p.N418S | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV56657573; called by muse, mutect2, varscan2
- LMNTD1 | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs1174162773, COSV51445878; called by muse, mutect2, varscan2
- MEN1 | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53642046; called by muse, mutect2, varscan2
- OR1C1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs373256453, COSV68715606; called by muse, mutect2, varscan2
- PIK3R1 | c.1286C>A p.S429Y (on ENST00000521381 / NM_181523.3; = p.S159Y on NM_181504.4) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57128236, COSV57139273; called by muse, mutect2, varscan2
- PRG2 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV61293372; called by muse, mutect2
- SHTN1 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as rs905104409, COSV53381273; called by muse, mutect2, varscan2
- SPPL2B | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV66316897; called by muse, mutect2, varscan2
- STXBP4 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as rs774093883, COSV64464388; called by muse, mutect2, varscan2
- TNFRSF4 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs775900244, COSV55418642; ClinVar: uncertain significance; called by muse, mutect2
- TUBA3C | c.1141A>T p.T381S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.307); catalogued as COSV68027964; called by muse, mutect2, varscan2
- RNF19B | c.1423_1424dup p.L476Pfs*15 | Frame Shift Ins (INS) | VAF 28/82 reads (34%) | called by mutect2, pindel, varscan2
- TP53 | c.999_1010del p.G334_R337del | In Frame Del (DEL) | VAF 6/16 reads (38%) | called by mutect2, varscan2
- CFAP299 | c.246G>A p.T82= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as rs141410009; called by muse, mutect2, varscan2
- DNAI3 | c.2121G>A p.P707= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs1258613470, COSV54001709; called by muse, mutect2, varscan2
- FOXD4L6 | c.780C>T p.Y260= | Silent (SNP) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- IFNW1 | c.402G>A p.G134= | Silent (SNP) | VAF 48/148 reads (32%) | catalogued as rs770636712, COSV66521965; called by muse, mutect2, varscan2
- IRGC | c.1053C>T p.S351= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs543218904, COSV54982662, COSV54983610; called by muse, mutect2, varscan2
- PCDHB12 | c.9C>T p.N3= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as rs970749047, COSV53395031; called by muse, mutect2, varscan2
- PCDHB15 | c.1701C>T p.N567= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs781920155, COSV51265454; called by muse, varscan2
- PDZD7 | c.165C>A p.P55= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as COSV56519572; called by muse, mutect2, varscan2
- PRG2 | c.303C>T p.I101= | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as COSV61293381; called by muse, mutect2
- RELB | c.192C>T p.N64= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as rs1379722953, COSV55509473; called by muse, mutect2, varscan2
- S1PR5 | c.636C>T p.Y212= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs189645975; called by muse, mutect2, varscan2
- SKOR1 | c.453C>T p.C151= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as rs1439357317, COSV58244968; called by muse, mutect2
- SPATS2L | c.856C>T p.L286= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as COSV62346884; called by muse, mutect2, varscan2
